CCDI case PBCDNM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/eaa03eed-d326-4dea-81cd-3bd72da44a94

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.9 years (2,142 days).

Biospecimens (3 samples)
- Sample 0DPBFF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPBFY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPBGA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
